Somatic mutation profile of cancer-model specimen HCM-BROD-0557-C43-85M (2D Modified Conditionally Reprogrammed Cells, passage 6; aliquot HCM-BROD-0557-C43-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0557-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 31.6 years (11,559 days).
Specimen HCM-BROD-0557-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ec31f41-b1bf-41d5-9586-51449dea5431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0557-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0557-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcf8acd7-3bc1-4851-9670-376c08d44b4b

The open-access MAF lists 541 somatic variants for this specimen: 348 protein-altering or splice-affecting, 170 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 320, Silent 170, Intron 13, Nonsense Mutation 13, 5'Flank 5, Frame Shift Del 5, Splice Region 4, 3'UTR 3, Splice Site 3, Frame Shift Ins 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 161/247 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- A4GNT | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs892441560; called by muse, mutect2, varscan2
- ACKR3 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 248/487 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56020440, COSV56021095; called by muse, mutect2, varscan2
- ADGRE1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV99165303; called by muse, mutect2, varscan2
- AGBL4 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1205278617; called by muse, mutect2, varscan2
- ALB | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 197/293 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55742933; called by muse, mutect2, varscan2
- ALS2CL | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 137/216 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59673039; called by muse, mutect2
- AMY2A | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70214313, COSV70214392; called by muse, mutect2, varscan2
- AMY2A | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1233637366, COSV101340608; called by muse, mutect2, varscan2
- APCS | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 154/252 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs746370899, COSV54818560; called by muse, mutect2, varscan2
- ARHGEF17 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 369/765 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs764091725; called by muse, mutect2, varscan2
- ATP6V0A2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 127/206 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV57747578; called by muse, mutect2, varscan2
- BEST2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 237/446 reads (53%) | catalogued as rs776776362; called by muse, mutect2, varscan2
- C11orf58 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 218/374 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57178116; called by muse, mutect2, varscan2
- C11orf58 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 216/370 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99930391; called by muse, mutect2, varscan2
- CACNA2D3 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 158/244 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55535361; called by muse, mutect2, varscan2
- CANT1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 211/459 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as rs748328987; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, mutect2, varscan2
- CD109 | c.4208C>T p.S1403F | Missense Mutation (SNP) | VAF 77/317 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV54645579; called by muse, mutect2
- CD55 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs924315999, COSV58576904; called by muse, mutect2, varscan2
- CD55 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201591726, COSV58577432; called by muse, mutect2, varscan2
- CDK12 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 160/320 reads (50%) | catalogued as COSV71002558; called by muse, mutect2, varscan2
- CEACAM16 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 209/478 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1424899201; called by muse, mutect2, varscan2
- CFAP44 | c.4909G>A p.D1637N | Missense Mutation (SNP) | VAF 155/254 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs557730278, COSV57661548; called by muse, mutect2, varscan2
- CHL1 | c.3136C>T p.R1046C (on ENST00000397491 / NM_001253387.1; = p.R1062C on NM_006614.4) | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs555557287, COSV56600202; called by muse, mutect2
- CILP | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 116/196 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV56021717; called by muse, mutect2, varscan2
- CLASP2 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.909); catalogued as rs1369924707, COSV100224038; called by muse, mutect2, varscan2
- CNTNAP2 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 170/309 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100663519; called by muse, mutect2, varscan2
- COL1A2 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 192/353 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs72659343, CM041284, COSV51955047; called by muse, mutect2, varscan2
- COL5A1 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 379/382 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV65669642; called by muse, mutect2, varscan2
- CRB1 | c.4130G>A p.G1377E | Missense Mutation (SNP) | VAF 176/258 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052327653, COSV66349180; called by muse, mutect2, varscan2
- CSMD1 | c.10409C>T p.P3470L (on ENST00000520002; = p.P3469L on NM_033225.6) | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs767156556; called by muse, mutect2, varscan2
- CSMD1 | c.2653C>T p.R885C (on ENST00000520002; = p.R884C on NM_033225.6) | Missense Mutation (SNP) | VAF 252/370 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310702695, COSV59352917, COSV99064856; called by muse, mutect2, varscan2
- CSMD3 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.931); catalogued as COSV52167315, COSV52262612; called by muse, mutect2, varscan2
- CTNNA3 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 127/136 reads (93%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as rs1392043478; called by muse, mutect2, varscan2
- CYLC2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 256/259 reads (99%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV66339524; called by muse, mutect2, varscan2
- CYP2D6 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 291/710 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs747089665; called by muse, mutect2, varscan2
- DEFB119 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 135/268 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs267605872, COSV59266560; called by muse, mutect2, varscan2
- DLX5 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99756472; called by muse, mutect2, varscan2
- DNAH1 | c.10602G>A p.M3534I | Missense Mutation (SNP) | VAF 167/243 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs763222753; called by muse, mutect2, varscan2
- DNAH5 | c.11031G>A p.V3677= | Splice Region (SNP) | VAF 169/354 reads (48%) | catalogued as rs1300306339, COSV99453372; called by muse, mutect2, varscan2
- DNAH6 | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs772882396, COSV52860572; called by muse, mutect2, varscan2
- DNAJC8 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1370615414; called by muse, mutect2, varscan2
- DSCAM | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 489/723 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68024399; called by muse, mutect2, varscan2
- EPHA3 | c.2853G>A p.M951I | Missense Mutation (SNP) | VAF 102/154 reads (66%) | SIFT tolerated (0.74); PolyPhen benign (0.037); catalogued as COSV60729791; called by muse, mutect2, varscan2
- ERCC2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 366/676 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.15); catalogued as rs1363432651, COSV55541226; called by muse, mutect2
- ERICH1 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 161/517 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as rs1285611999; called by muse, mutect2, varscan2
- EYA1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs780203392, COSV58160409; called by muse, mutect2, varscan2
- FBN1 | c.8189G>A p.R2730Q | Missense Mutation (SNP) | VAF 193/292 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs200231626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 229/304 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs376398925, COSV52514403; called by muse, mutect2, varscan2
- FBXW8 | c.1162G>A p.G388S (on ENST00000309909; = p.G426S on NM_012174.1) | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV99997461; called by muse, mutect2, varscan2
- FER1L5 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 178/315 reads (57%) | catalogued as rs866147948, COSV70069045; called by muse, mutect2, varscan2
- FNDC3A | c.2179C>T p.P727S (on ENST00000492622 / NM_001079673.2; = p.P671S on NM_014923.5) | Missense Mutation (SNP) | VAF 129/280 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs747587950; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GLI2 | c.2393C>T p.S798L (on ENST00000361492 / NM_001374353.1; = p.S815L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 312/715 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1026630572; called by muse, mutect2, varscan2
- GPHN | c.1690C>T p.R564C (on ENST00000315266 / NM_001377519.1; = p.R597C on NM_020806.5) | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1360125120, COSV104400759; called by muse, mutect2, varscan2
- GPI | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 157/315 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs767547881; called by muse, mutect2, varscan2
- GPI | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 161/323 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as rs1320084711, COSV62893917; called by muse, mutect2, varscan2
- GPR176 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV100137071; called by muse, mutect2, varscan2
- GRIA4 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 147/283 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56891574; called by muse, mutect2, varscan2
- H1-7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 305/470 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs1373989811; called by muse, mutect2, varscan2
- HDAC9 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 207/464 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs527740786, COSV67781752; called by muse, mutect2, varscan2
- HIP1R | c.3073C>T p.R1025W | Missense Mutation (SNP) | VAF 117/390 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs149673932; called by muse, varscan2
- HLA-G | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64406883; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 207/463 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1387817513; called by muse, mutect2, varscan2
- HS3ST1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 156/251 reads (62%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs368275390; called by mutect2, varscan2
- IGSF9 | c.1909C>T p.R637W (on ENST00000368094 / NM_001135050.2; = p.R621W on NM_020789.4) | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1480973609, COSV100829611; called by muse, mutect2, varscan2
- IMPG1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 143/213 reads (67%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100886337, COSV64055776; called by muse, mutect2, varscan2
- INPP5B | c.2174G>A p.R725K (on ENST00000373023; = p.R645K on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100886603; called by muse, mutect2, varscan2
- INPPL1 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 205/404 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53359298; called by muse, mutect2, varscan2
- ITGB2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 313/687 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1038898860, COSV56614762; called by muse, mutect2, varscan2
- IYD | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as rs777194249, COSV57604315; called by muse, mutect2, varscan2
- JAKMIP1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 136/212 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV51522350; called by muse, mutect2, varscan2
- KCNH6 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs200388894, COSV59005511; called by muse, mutect2, varscan2
- KDM4B | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 253/464 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV50208384; called by muse, mutect2, varscan2
- KIF1B | c.4714G>A p.E1572K (on ENST00000377086 / NM_001365952.1; = p.E1526K on NM_015074.3) | Missense Mutation (SNP) | VAF 132/207 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.381); catalogued as rs1472927510; called by muse, mutect2, varscan2
- KIF2B | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 256/541 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.231); catalogued as COSV99275798; called by muse, mutect2, varscan2
- KIRREL1 | c.917T>C p.F306S | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV63291737; called by muse, mutect2, varscan2
- KLRF1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as COSV99684382; called by muse, mutect2, varscan2
- KRBA1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 219/546 reads (40%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1457120871; called by muse, mutect2
- KRT85 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 96/156 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs756221275, COSV57737514, COSV99225480; called by muse, mutect2, varscan2
- KRTAP27-1 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 205/597 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs753785111; called by muse, mutect2, varscan2
- LDAH | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 191/380 reads (50%) | catalogued as rs1337123037, COSV52970284; called by muse, mutect2, varscan2
- LRGUK | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs953665896; called by muse, mutect2, varscan2
- LRP1B | c.8314C>T p.R2772C | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as rs1247290776; called by muse, mutect2, varscan2
- LTF | c.1216G>C p.G406R | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV99212230; called by muse, mutect2, varscan2
- MAGEC1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 274/275 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as rs374380387; called by muse, mutect2, varscan2
- MAP7D3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 184/187 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773689546, COSV60170155; called by muse, mutect2, varscan2
- MED12L | c.6136C>T p.Q2046* | Nonsense Mutation (SNP) | VAF 159/259 reads (61%) | catalogued as COSV56386065; called by muse, mutect2, varscan2
- MGAM2 | c.4597C>T p.P1533S | Missense Mutation (SNP) | VAF 102/191 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101522957; called by muse, mutect2, varscan2
- MGAT1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 156/554 reads (28%) | PolyPhen benign (0.052); catalogued as rs1230770357, COSV57134298; called by muse, mutect2, varscan2
- MIB2 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 157/484 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV61542620; called by muse, mutect2, varscan2
- MPP7 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 80/82 reads (98%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs767641039, COSV61731060; called by muse, varscan2
- MUC12 | c.10477C>T p.R3493C (on ENST00000379442; = p.R3350C on NM_001164462.1) | Missense Mutation (SNP) | VAF 240/3494 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1159978317; called by muse, mutect2
- MUC16 | c.35800T>A p.F11934I | Missense Mutation (SNP) | VAF 168/390 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV67463794; called by muse, mutect2, varscan2
- MUC16 | c.25315G>A p.E8439K | Missense Mutation (SNP) | VAF 232/433 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.047); catalogued as rs758147569; called by muse, mutect2, varscan2
- MXRA5 | c.7639C>T p.P2547S | Missense Mutation (SNP) | VAF 104/109 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54228015; called by muse, mutect2, varscan2
- MYCN | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 185/387 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55257630; called by muse, mutect2, varscan2
- MYOCD | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 220/409 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767925734, COSV58498174, COSV58501218; called by muse, mutect2, varscan2
- NDRG4 | c.92C>T p.P31L (on ENST00000570248 / NM_001378344.1; = p.P63L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 321/324 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773985953; called by muse, mutect2, varscan2
- NELL1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1282602015, COSV54266218; called by muse, mutect2, varscan2
- NLRP11 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 141/334 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1419096001; called by muse, mutect2, varscan2
- NOS1 | c.2962+1G>A p.X988_splice | Splice Site (SNP) | VAF 71/201 reads (35%) | catalogued as COSV57616870; called by muse, mutect2, varscan2
- NOTCH2 | c.5123C>T p.S1708F | Missense Mutation (SNP) | VAF 124/209 reads (59%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs761415665, COSV56687314, COSV56702208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUGGC | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 187/279 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs200299828; called by muse, mutect2, varscan2
- OCM2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs761610491, COSV99990764; called by muse, mutect2, varscan2
- OR10J3 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs748268654, COSV100171598, COSV59955282; called by muse, mutect2, varscan2
- OR2W3 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 89/298 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64456004, COSV64456927; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR5D14 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV59456072; called by muse, mutect2, varscan2
- OR8B2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1443464287; called by muse, mutect2
- OR8D4 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs866199393, COSV58429312; called by muse, mutect2
- OTX2 | c.506C>T p.S169F (on ENST00000408990 / NM_172337.3; = p.S177F on NM_021728.4) | Missense Mutation (SNP) | VAF 330/562 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59766304; called by muse, mutect2, varscan2
- PAPLN | c.1790G>C p.G597A (on ENST00000554301; = p.G570A on NM_173462.4) | Missense Mutation (SNP) | VAF 404/758 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV53716638; called by mutect2, varscan2
- PCDH11Y | c.263C>T p.S88F (on ENST00000400457 / NM_032973.2; = p.S77F on NM_032971.3) | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53087313; called by muse, mutect2, varscan2
- PCDH18 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs1430122137, COSV61267510; called by muse, mutect2, varscan2
- PCDHGA7 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 268/376 reads (71%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as COSV53946956; called by muse, mutect2, varscan2
- PCLO | c.5621C>T p.P1874L | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371631647, COSV61631945; called by muse, mutect2, varscan2
- PGBD1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 138/236 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV52556944; called by muse, mutect2, varscan2
- PLS3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56776518; called by muse, mutect2, varscan2
- PLVAP | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 326/578 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.423); catalogued as rs561048879, COSV53083952, COSV53088077; called by muse, mutect2, varscan2
- POM121L2 | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66277542; called by muse, mutect2, varscan2
- PPP6R1 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 156/295 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs1157181885; called by muse, mutect2, varscan2
- PRKAA2 | c.786A>G p.I262M | Missense Mutation (SNP) | VAF 137/207 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771303312; called by muse, mutect2, varscan2
- PSMD6 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 96/330 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs1391025180; called by mutect2, varscan2
- PTPRD | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 188/192 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV61936192, COSV61975980; called by muse, mutect2, varscan2
- PTPRT | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 156/364 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.065); catalogued as rs539998222, COSV61971201; called by muse, mutect2, varscan2
- RAB43 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 116/197 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs748757556; called by muse, mutect2, varscan2
- RANBP2 | c.3275C>T p.T1092I | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1435623130; called by muse, mutect2, varscan2
- REV3L | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 104/106 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs746372132, COSV62615391; called by muse, mutect2, varscan2
- RGPD3 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 230/544 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58738872; called by muse, varscan2
- RNF113B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs199939990, COSV57434212; called by muse, mutect2, varscan2
- RNF213 | c.6070C>T p.R2024* | Nonsense Mutation (SNP) | VAF 239/467 reads (51%) | catalogued as COSV60396335; called by muse, mutect2, varscan2
- RPGRIP1 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 144/342 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376213645; called by muse, mutect2, varscan2
- RPS6KB2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1314670038; called by muse, mutect2, varscan2
- RPS6KB2 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 150/330 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748416853; called by muse, mutect2, varscan2
- RYR3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370528698; called by muse, mutect2, varscan2
- SEPTIN9 | c.149C>T p.P50L (on ENST00000427177 / NM_001113491.2; = p.P32L on NM_006640.4) | Missense Mutation (SNP) | VAF 201/451 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV61210110; called by muse, mutect2, varscan2
- SEZ6L | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 153/335 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50699220; called by muse, mutect2, varscan2
- SIK3 | c.2768C>T p.S923F (on ENST00000445177 / NM_001366686.2; = p.S881F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/262 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV52611461; called by muse, mutect2, varscan2
- SKAP2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344115486; called by muse, mutect2, varscan2
- SLC22A12 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 242/469 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs759297223, COSV60572779; called by muse, mutect2, varscan2
- SLC35F3 | c.125C>T p.P42L (on ENST00000366617 / NM_001300845.1; = p.P111L on NM_173508.4) | Missense Mutation (SNP) | VAF 249/366 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1343882726, COSV64020069; called by muse, mutect2, varscan2
- SLC5A5 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99033085; called by muse, mutect2, varscan2
- SLC9A5 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 208/209 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1316587688; called by muse, mutect2, varscan2
- SMO | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 350/678 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1189276452; called by muse, varscan2
- SNX4 | c.399G>A p.R133= | Splice Region (SNP) | VAF 60/168 reads (36%) | catalogued as rs1477156669; called by muse, mutect2, varscan2
- SPATA13 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 195/421 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as rs528255708, COSV57975958; called by muse, mutect2, varscan2
- TANC2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 118/257 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67343879; called by muse, mutect2, varscan2
- TCAP | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV54092384; called by muse, mutect2, varscan2
- TET3 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69645315; called by muse, mutect2, varscan2
- TGIF2LX | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs1244960748; called by muse, mutect2, varscan2
- TGM7 | c.1680G>A p.E560= | Splice Region (SNP) | VAF 99/162 reads (61%) | catalogued as COSV71772907; called by muse, mutect2, varscan2
- TIMELESS | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 62/176 reads (35%) | catalogued as rs267603584, COSV57508974, COSV57515293; called by muse, mutect2, varscan2
- TMEM132E | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 244/588 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776520313; called by muse, mutect2, varscan2
- TMEM185B | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 211/480 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.079); catalogued as rs899097862; called by muse, mutect2, varscan2
- TMPRSS9 | c.581C>T p.S194F (on ENST00000648592; = p.S160F on NM_182973.2) | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs770258343, COSV60227090; called by muse, mutect2, varscan2
- TNFRSF17 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50000400; called by mutect2, varscan2
- TRIM25 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 187/387 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs533748559; called by muse, mutect2, varscan2
- UBR2 | c.4118C>T p.A1373V | Missense Mutation (SNP) | VAF 156/244 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV65752050; called by muse, mutect2, varscan2
- UGT2A1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036004763; called by muse, mutect2, varscan2
- UNC13A | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 246/604 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs756578402; called by muse, varscan2
- UNC79 | c.6643-1G>A p.X2215_splice (on ENST00000393151 / NM_001346218.2; = p.X2038_splice on NM_020818.5) | Splice Site (SNP) | VAF 129/311 reads (41%) | catalogued as COSV56371891, COSV56399831; called by muse, mutect2, varscan2
- UPK1B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs769296250, COSV51766303; called by muse, mutect2, varscan2
- VPS72 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs753843573, COSV99765980; called by muse, mutect2, varscan2
- VWA5B1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 211/339 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as rs1438103590; called by muse, mutect2, varscan2
- WFDC5 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 243/510 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs1366889691; called by muse, mutect2, varscan2
- WNT2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 160/372 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55413034; called by muse, mutect2, varscan2
- XIRP2 | c.389G>A p.R130K (on ENST00000628543; = p.R305K on NM_152381.6) | Missense Mutation (SNP) | VAF 134/248 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99747444; called by muse, mutect2, varscan2
- ZC3H6 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV59670659; called by muse, mutect2, varscan2
- ZC3H7B | c.2866G>C p.D956H | Missense Mutation (SNP) | VAF 109/498 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as COSV60961738; called by muse, mutect2, varscan2
- ZFHX4 | c.7298C>T p.S2433L | Missense Mutation (SNP) | VAF 297/454 reads (65%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1290135493, COSV99257705; called by muse, varscan2
- ZNF217 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 222/469 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs771475503; called by muse, mutect2, varscan2
- ZNF268 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.42); catalogued as COSV57214426; called by muse, mutect2, varscan2
- ZNF618 | c.709G>A p.E237K (on ENST00000374126 / NM_001318042.2; = p.E205K on NM_133374.2) | Missense Mutation (SNP) | VAF 337/341 reads (99%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.318); catalogued as rs1335639588; called by muse, mutect2, varscan2
- ZNF626 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 100/236 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV74129566, COSV74130913; called by muse, mutect2, varscan2
- ZSCAN4 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 88/203 reads (43%) | catalogued as rs267605731; called by muse, mutect2, varscan2
- AADACL3 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA12 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 163/354 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ACO2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 129/255 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACRV1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ACSM2A | c.573G>A p.W191* (on ENST00000219054; = p.W112* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 89/187 reads (48%) | called by muse, mutect2, varscan2
- ADAM28 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 152/240 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL3 | c.2503G>A p.G835S | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGER | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 319/486 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- AHSG | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP8L | c.1087_1089delinsTG p.R363* | Frame Shift Del (DEL) | VAF 164/520 reads (32%) | called by pindel, varscan2*
- AKNAD1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 157/232 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- AL441992.2 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ANAPC7 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANK3 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6865G>T p.D2289Y | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ATP8A1 | c.2944A>T p.N982Y | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AVL9 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 132/237 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BICRA | c.4045C>T p.P1349S | Missense Mutation (SNP) | VAF 282/575 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BPIFC | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 204/484 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BTBD8 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 117/204 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- C1orf116 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 201/305 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- C1orf74 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 88/270 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, varscan2
- C4A | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 185/476 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CABLES2 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 126/274 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.146); called by mutect2, varscan2
- CABP2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 260/487 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CADM3 | c.517C>T p.H173Y (on ENST00000368125 / NM_001127173.3; = p.H207Y on NM_021189.5) | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CALCB | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 352/524 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- CALCRL | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 133/299 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CAMK4 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 350/476 reads (74%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMTA1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 277/408 reads (68%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCL1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 147/296 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC42BPB | c.3309+1G>A p.X1103_splice | Splice Site (SNP) | VAF 186/337 reads (55%) | called by muse, mutect2, varscan2
- CDC42BPB | c.3309G>A p.K1103= | Splice Region (SNP) | VAF 186/338 reads (55%) | called by muse, mutect2, varscan2
- CDH11 | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 216/221 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR3 | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 144/407 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CEMIP | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP99 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CFH | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMPK2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 46/820 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- CMYA5 | c.11113C>T p.P3705S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG7 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 115/243 reads (47%) | called by muse, mutect2, varscan2
- CR2 | c.230_231delinsC p.K77Tfs*19 | Frame Shift Del (DEL) | VAF 151/383 reads (39%) | called by pindel, varscan2*
- CSDE1 | c.596T>A p.F199Y (on ENST00000358528 / NM_001007553.3; = p.F168Y on NM_007158.6) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CSMD2 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CSNKA2IP | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 208/348 reads (60%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.996); called by muse, varscan2
- CYP3A4 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 140/298 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DCAF12 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 348/350 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DCLK1 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.7417C>T p.L2473F | Missense Mutation (SNP) | VAF 251/526 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- DNAJC8 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DSP | c.2672A>T p.Y891F | Missense Mutation (SNP) | VAF 180/275 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DUOX2 | c.3023C>A p.P1008H | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- EP400 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- FAF2 | c.1200del p.K400Nfs*43 | Frame Shift Del (DEL) | VAF 201/399 reads (50%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.1937C>T p.A646V (on ENST00000449352 / NM_001098794.2; = p.A660V on NM_032127.4) | Missense Mutation (SNP) | VAF 216/723 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCC | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FLG | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 165/271 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- FMO1 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 144/230 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FN1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 207/461 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FXR2 | c.316dup p.Y106Lfs*5 | Frame Shift Ins (INS) | VAF 107/260 reads (41%) | called by mutect2, varscan2
- FXR2 | c.315delinsTT p.E105Dfs*6 | Frame Shift Ins (INS) | VAF 112/389 reads (29%) | called by mutect2*, pindel, varscan2*
- GALNT9 | c.841A>C p.T281P | Missense Mutation (SNP) | VAF 228/338 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- GKN3P | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 177/369 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPBP1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- HPS4 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 193/407 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HRNR | c.5759C>T p.S1920F | Missense Mutation (SNP) | VAF 235/1917 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HSD17B13 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IER3 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 173/525 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGLV1-44 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGLV4-69 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 134/284 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITGA2 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KALRN | c.3151C>T p.L1051F | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT2 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KDM5C | c.4235C>T p.T1412I | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KLHL32 | c.743A>T p.H248L | Missense Mutation (SNP) | VAF 165/264 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAT | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 218/453 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LOXHD1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 164/305 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRCH2 | c.2269A>G p.T757A | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP3 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 147/604 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC53 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 187/267 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LUZP4 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 235/237 reads (99%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAGI1 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBOAT1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MFNG | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MGAT4C | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 109/172 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MON2 | c.5099C>T p.P1700L | Missense Mutation (SNP) | VAF 158/250 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- MRC2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 163/349 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRC2 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 132/328 reads (40%) | called by muse, mutect2, varscan2
- MTAP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 232/234 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, varscan2
- MTREX | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MUC2 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 488/743 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUCL3 | c.1448A>G p.N483S (on ENST00000304311; = p.N1359S on NM_080870.4) | Missense Mutation (SNP) | VAF 294/459 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NCAM2 | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 205/305 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDNF | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NEB | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP2 | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 263/598 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOXO1 | c.919G>A p.G307R (on ENST00000397280 / NM_172168.3; = p.G301R on NM_144603.4) | Missense Mutation (SNP) | VAF 335/718 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN2 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 297/608 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NUP98 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 290/467 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NUTM2G | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 404/412 reads (98%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NXPE4 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 119/257 reads (46%) | called by muse, mutect2, varscan2
- OR10A3 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 264/831 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR2T27 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4D10 | c.202A>T p.I68F | Missense Mutation (SNP) | VAF 181/407 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6S1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 135/284 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OR6V1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 274/588 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PALM | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 334/633 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2
- PAPLN | c.2600G>A p.G867E (on ENST00000554301; = p.G840E on NM_173462.4) | Missense Mutation (SNP) | VAF 398/682 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEG3 | c.3044C>A p.P1015H | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PIWIL4 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PKHD1L1 | c.9310A>T p.T3104S | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PLEKHH2 | c.1829C>T p.T610I | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PPRC1 | c.3767C>T p.S1256F | Missense Mutation (SNP) | VAF 172/178 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRDM6 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 284/394 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PSKH2 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RARG | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 175/252 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- REV3L | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 104/106 reads (98%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RNLS | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 213/214 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RPH3A | c.1561C>T p.P521S (on ENST00000389385 / NM_001143854.2; = p.P517S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2
- RTN4R | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 229/485 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR3 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCAMP5 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 193/281 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SGK1 | c.669A>T p.L223F | Missense Mutation (SNP) | VAF 90/91 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3PXD2A | c.1301C>T p.S434F (on ENST00000369774 / NM_001365079.1; = p.S406F on NM_014631.2) | Missense Mutation (SNP) | VAF 184/187 reads (98%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SHROOM3 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 152/487 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- SLC10A6 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A9 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEN | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 164/241 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- SPIDR | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPTBN1 | c.4691G>A p.R1564K | Missense Mutation (SNP) | VAF 207/430 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SSR1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SUSD1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 255/256 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SVEP1 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 383/384 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC2 | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 249/254 reads (98%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, varscan2
- TECTA | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TGIF2LX | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 167/168 reads (99%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TIMELESS | c.3347C>T p.P1116L | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TLR4 | c.1111G>A p.D371N (on ENST00000355622 / NM_138554.5; = p.D331N on NM_003266.4) | Missense Mutation (SNP) | VAF 285/288 reads (99%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132B | c.2008C>T p.L670F | Missense Mutation (SNP) | VAF 228/349 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMEM132E | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 245/592 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM169 | c.86del p.L29Rfs*56 | Frame Shift Del (DEL) | VAF 186/382 reads (49%) | called by mutect2, pindel*, varscan2
- TMEM211 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TMEM247 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 256/572 reads (45%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMPRSS11B | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNPO3 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRBV6-1 | c.197A>C p.Y66S | Missense Mutation (SNP) | VAF 119/245 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, varscan2
- TRBV6-1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TTC34 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 295/454 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTYH2 | c.778C>A p.L260M | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.144); called by muse, mutect2
- UBE2E2 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 176/253 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- UBQLN3 | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 76/470 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- UFL1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- UNC13C | c.5539G>A p.G1847S | Missense Mutation (SNP) | VAF 97/165 reads (59%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- VN1R4 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13D | c.2734C>T p.Q912* | Nonsense Mutation (SNP) | VAF 117/200 reads (59%) | called by muse, mutect2, varscan2
- VRK3 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 143/294 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWDE | c.1049T>G p.L350W | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- XRCC6 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 204/410 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- YME1L1 | c.1164del p.A389Pfs*52 (on ENST00000326799 / NM_139312.3; = p.A332Pfs*52 on NM_014263.4) | Frame Shift Del (DEL) | VAF 142/189 reads (75%) | called by mutect2, pindel, varscan2
- ZAR1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 146/463 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED9 | c.3344T>C p.L1115P | Missense Mutation (SNP) | VAF 172/270 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZEB1 | c.3080G>A p.S1027N | Missense Mutation (SNP) | VAF 181/182 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ZFHX4 | c.7483T>G p.C2495G | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF160 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF280B | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 232/489 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF420 | c.627A>T p.Q209H | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF443 | c.1887T>A p.S629R | Missense Mutation (SNP) | VAF 202/392 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF585A | c.2087G>A p.G696E (on ENST00000292841 / NM_001288800.2; = p.G641E on NM_152655.3) | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF729 | c.534A>T p.K178N | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABCB5 | c.1731C>T p.I577= (on ENST00000404938 / NM_001163941.2; = p.I132= on NM_178559.6) | Silent (SNP) | VAF 130/285 reads (46%) | catalogued as rs149931729; called by muse, mutect2, varscan2
- ADAM19 | c.2730G>A p.V910= | Silent (SNP) | VAF 98/444 reads (22%) | called by muse, mutect2, varscan2
- ADHFE1 | c.1293C>T p.P431= | Silent (SNP) | VAF 171/255 reads (67%) | catalogued as rs754414045; called by muse, mutect2, varscan2
- AK5 | c.1506G>A p.R502= (on ENST00000354567 / NM_174858.3; = p.R476= on NM_012093.4) | Silent (SNP) | VAF 104/318 reads (33%) | called by muse, mutect2, varscan2
- AKAP6 | c.6189C>T p.I2063= | Silent (SNP) | VAF 255/440 reads (58%) | catalogued as COSV55232489; called by muse, mutect2, varscan2
- AKR1B10 | c.225C>T p.I75= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as rs186829500, COSV62055233; called by muse, mutect2, varscan2
- ANAPC7 | c.1197C>T p.A399= | Silent (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- AP3B2 | c.2211G>A p.Q737= | Silent (SNP) | VAF 142/218 reads (65%) | catalogued as rs544059884, COSV99916859; called by muse, mutect2, varscan2
- ARL9 | c.21G>A p.K7= | Silent (SNP) | VAF 110/166 reads (66%) | called by muse, mutect2, varscan2
- ASIC2 | c.153C>T p.G51= | Silent (SNP) | VAF 247/485 reads (51%) | catalogued as rs1391455208; called by muse, mutect2, varscan2
- ATP1A3 | c.798C>T p.D266= (on ENST00000545399 / NM_001256214.2; = p.D253= on NM_152296.5) | Silent (SNP) | VAF 230/446 reads (52%) | catalogued as rs369131791; called by muse, mutect2, varscan2
- ATXN3 | c.1011C>T p.F337= | Silent (SNP) | VAF 50/590 reads (8%) | called by muse, mutect2
- BAZ1B | c.363C>T p.D121= | Silent (SNP) | VAF 84/209 reads (40%) | called by muse, mutect2, varscan2
- CABLES2 | c.732G>A p.K244= | Silent (SNP) | VAF 128/278 reads (46%) | called by mutect2, varscan2
- CAPN11 | c.255C>T p.F85= | Silent (SNP) | VAF 200/293 reads (68%) | catalogued as COSV67236221, COSV67240276; called by muse, mutect2, varscan2
- CARMIL3 | c.838C>T p.L280= | Silent (SNP) | VAF 170/334 reads (51%) | called by muse, mutect2, varscan2
- CCDC151 | c.457C>T p.L153= | Silent (SNP) | VAF 198/343 reads (58%) | catalogued as rs201858348; called by muse, mutect2, varscan2
- CCDC81 | c.603G>A p.R201= (on ENST00000445632 / NM_001156474.2; = p.R111= on NM_021827.4) | Silent (SNP) | VAF 143/281 reads (51%) | catalogued as rs763510233; called by muse, mutect2, varscan2
- CCNB3 | c.1351T>C p.L451= | Silent (SNP) | VAF 302/304 reads (99%) | called by muse, mutect2, varscan2
- CCNY | c.957C>T p.S319= | Silent (SNP) | VAF 164/167 reads (98%) | catalogued as rs766833961; called by muse, varscan2
- CD109 | c.4209C>T p.S1403= | Silent (SNP) | VAF 67/279 reads (24%) | called by muse, mutect2, varscan2
- CEACAM5 | c.1935C>T p.I645= | Silent (SNP) | VAF 228/460 reads (50%) | called by muse, mutect2, varscan2
- CEP112 | c.1779G>A p.R593= | Silent (SNP) | VAF 167/362 reads (46%) | called by muse, mutect2, varscan2
- CFAP46 | c.1896C>T p.D632= | Silent (SNP) | VAF 232/234 reads (99%) | called by muse, mutect2, varscan2
- CFAP70 | c.2196G>A p.L732= | Silent (SNP) | VAF 116/116 reads (100%) | called by muse, mutect2, varscan2
- CFHR1 | c.960G>A p.G320= | Silent (SNP) | VAF 136/200 reads (68%) | catalogued as COSV57628994; called by muse, mutect2, varscan2
- CHERP | c.1188G>A p.G396= | Silent (SNP) | VAF 206/459 reads (45%) | catalogued as rs780905129; called by muse, mutect2, varscan2
- CMYA5 | c.8170C>T p.L2724= | Silent (SNP) | VAF 95/357 reads (27%) | catalogued as rs1320822319, COSV101484347; called by muse, mutect2, varscan2
- COL11A1 | c.1056G>A p.R352= | Silent (SNP) | VAF 157/248 reads (63%) | catalogued as rs762727530, COSV62171357; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRTAC1 | c.1359G>A p.R453= | Silent (SNP) | VAF 224/227 reads (99%) | called by muse, mutect2, varscan2
- CSMD2 | c.3120G>A p.E1040= | Silent (SNP) | VAF 69/253 reads (27%) | catalogued as COSV53917290, COSV53961596; called by muse, mutect2, varscan2
- CYP2D6 | c.1239C>T p.F413= | Silent (SNP) | VAF 290/710 reads (41%) | called by muse, mutect2, varscan2
- DCAF4L1 | c.273G>A p.Q91= | Silent (SNP) | VAF 154/256 reads (60%) | called by muse, mutect2
- DCAF4L1 | c.1179C>T p.F393= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as rs1265511978; called by muse, mutect2, varscan2
- DGKI | c.2022C>T p.S674= | Silent (SNP) | VAF 163/378 reads (43%) | called by muse, mutect2, varscan2
- DHX30 | c.558C>T p.G186= (on ENST00000445061 / NM_138615.3; = p.G147= on NM_014966.3) | Silent (SNP) | VAF 91/294 reads (31%) | called by muse, mutect2, varscan2
- DLEC1 | c.606G>A p.R202= | Silent (SNP) | VAF 88/285 reads (31%) | catalogued as rs1228286789, COSV57298331; called by muse, mutect2, varscan2
- DLG2 | c.528C>T p.I176= | Silent (SNP) | VAF 208/486 reads (43%) | catalogued as rs769219035; called by muse, mutect2, varscan2
- DNAH6 | c.1368G>A p.T456= | Silent (SNP) | VAF 134/283 reads (47%) | catalogued as rs372969433; called by muse, mutect2, varscan2
- DNAH6 | c.10479G>A p.K3493= | Silent (SNP) | VAF 94/219 reads (43%) | called by muse, mutect2, varscan2
- DNAH9 | c.13119G>A p.Q4373= | Silent (SNP) | VAF 194/392 reads (49%) | catalogued as rs760755811; called by muse, mutect2
- DOCK6 | c.5463G>A p.Q1821= | Silent (SNP) | VAF 64/178 reads (36%) | called by muse, mutect2, varscan2
- DSC3 | c.2002C>T p.L668= | Silent (SNP) | VAF 150/316 reads (47%) | called by muse, mutect2, varscan2
- ELL | c.990C>T p.F330= | Silent (SNP) | VAF 160/281 reads (57%) | catalogued as COSV99443504; called by muse, mutect2, varscan2
- ERCC6 | c.1183C>T p.L395= | Silent (SNP) | VAF 216/219 reads (99%) | catalogued as rs767647833; called by muse, mutect2, varscan2
- FAM187B | c.777C>T p.S259= | Silent (SNP) | VAF 243/424 reads (57%) | catalogued as rs1330311719; called by muse, mutect2, varscan2
- FAN1 | c.771C>T p.F257= | Silent (SNP) | VAF 246/373 reads (66%) | catalogued as rs372989498; called by muse, mutect2
- FAT3 | c.4785A>G p.K1595= | Silent (SNP) | VAF 146/328 reads (45%) | called by muse, mutect2, varscan2
- FREM2 | c.5601C>T p.F1867= | Silent (SNP) | VAF 125/239 reads (52%) | catalogued as COSV54846828; called by muse, mutect2, varscan2
- FRMPD3 | c.1587G>A p.G529= | Silent (SNP) | VAF 219/224 reads (98%) | catalogued as COSV99346155; called by muse, mutect2, varscan2
- GDPD4 | c.57C>T p.V19= | Silent (SNP) | VAF 71/151 reads (47%) | called by muse, mutect2, varscan2
- GGT2 | c.1278C>T p.L426= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs1291901474; called by mutect2, varscan2
- GIPR | c.342C>T p.D114= | Silent (SNP) | VAF 127/280 reads (45%) | called by muse, mutect2, varscan2
- GJA10 | c.1182C>A p.P394= | Silent (SNP) | VAF 93/318 reads (29%) | called by muse, mutect2, varscan2
- GNPTAB | c.3711G>A p.R1237= | Silent (SNP) | VAF 119/194 reads (61%) | catalogued as rs1251057066; called by muse, mutect2, varscan2
- GPI | c.225G>A p.R75= | Silent (SNP) | VAF 150/393 reads (38%) | catalogued as rs1364734053; called by muse, mutect2, varscan2
- GRID2IP | c.774G>A p.P258= | Silent (SNP) | VAF 258/507 reads (51%) | catalogued as rs902347614; called by muse, mutect2, varscan2
- GRIN2A | c.2409G>A p.E803= | Silent (SNP) | VAF 153/322 reads (48%) | called by muse, mutect2, varscan2
- GRM3 | c.678G>A p.G226= | Silent (SNP) | VAF 175/392 reads (45%) | catalogued as rs745376739, COSV64479515; called by muse, mutect2, varscan2
- HEPHL1 | c.1857C>T p.N619= | Silent (SNP) | VAF 93/187 reads (50%) | called by muse, mutect2, varscan2
- HEYL | c.921G>A p.G307= | Silent (SNP) | VAF 134/433 reads (31%) | catalogued as rs554192451; called by muse, mutect2, varscan2
- HLA-G | c.774G>A p.R258= | Silent (SNP) | VAF 102/346 reads (29%) | called by muse, varscan2
- HMGB4 | c.501G>A p.R167= | Silent (SNP) | VAF 174/293 reads (59%) | called by muse, mutect2, varscan2
- HMSD | c.261G>A p.T87= | Silent (SNP) | VAF 89/203 reads (44%) | catalogued as rs1384875525, COSV101282944, COSV68816978; called by muse, mutect2, varscan2
- HOXD8 | c.234C>T p.P78= | Silent (SNP) | VAF 345/684 reads (50%) | catalogued as rs962288410; called by muse, mutect2, varscan2
- HTT | c.6850C>T p.L2284= | Silent (SNP) | VAF 215/327 reads (66%) | called by muse, mutect2, varscan2
- ICE1 | c.6696C>T p.S2232= | Silent (SNP) | VAF 266/586 reads (45%) | called by muse, mutect2, varscan2
- IDO1 | c.24C>T p.S8= | Silent (SNP) | VAF 95/168 reads (57%) | called by muse, mutect2, varscan2
- IFNW1 | c.64C>T p.L22= | Silent (SNP) | VAF 268/271 reads (99%) | called by muse, mutect2, varscan2
- IGFN1 | c.555G>A p.K185= | Silent (SNP) | VAF 165/274 reads (60%) | catalogued as rs780511622; called by muse, mutect2, varscan2
- IGSF10 | c.3402C>T p.S1134= | Silent (SNP) | VAF 148/248 reads (60%) | catalogued as COSV56791089; called by muse, mutect2, varscan2
- IGSF10 | c.1938G>A p.V646= | Silent (SNP) | VAF 103/323 reads (32%) | called by muse, mutect2, varscan2
- IGSF9 | c.1908C>G p.P636= (on ENST00000368094 / NM_001135050.2; = p.P620= on NM_020789.4) | Silent (SNP) | VAF 133/409 reads (33%) | called by muse, mutect2, varscan2
- IL1RL1 | c.1048C>T p.L350= | Silent (SNP) | VAF 121/303 reads (40%) | called by muse, mutect2, varscan2
- INF2 | c.999C>T p.T333= | Silent (SNP) | VAF 251/455 reads (55%) | called by muse, mutect2, varscan2
- INPPL1 | c.2157C>T p.S719= | Silent (SNP) | VAF 209/408 reads (51%) | called by muse, mutect2, varscan2
- INTS7 | c.366C>T p.T122= | Silent (SNP) | VAF 80/128 reads (63%) | catalogued as rs1356188614; called by muse, mutect2, varscan2
- IQCN | c.1638C>T p.S546= | Silent (SNP) | VAF 243/404 reads (60%) | called by muse, mutect2, varscan2
- KCNB2 | c.1371C>T p.A457= | Silent (SNP) | VAF 103/309 reads (33%) | called by muse, mutect2, varscan2
- KCNJ10 | c.471G>A p.L157= | Silent (SNP) | VAF 206/323 reads (64%) | called by muse, mutect2, varscan2
- KCNT1 | c.2052G>A p.S684= (on ENST00000488444; = p.S703= on NM_020822.3) | Silent (SNP) | VAF 623/625 reads (100%) | catalogued as rs767200583, COSV53706020; called by muse, mutect2, varscan2
- KDM5C | c.4236C>T p.T1412= | Silent (SNP) | VAF 245/245 reads (100%) | called by muse, mutect2, varscan2
- KERA | c.576G>A p.K192= | Silent (SNP) | VAF 93/261 reads (36%) | catalogued as COSV99899350; called by muse, mutect2, varscan2
- KIR3DL1 | c.306C>T p.S102= | Silent (SNP) | VAF 158/305 reads (52%) | catalogued as rs1229083521, COSV100428889; called by muse, mutect2, varscan2
- KIR3DL1 | c.840C>T p.F280= | Silent (SNP) | VAF 149/257 reads (58%) | catalogued as rs765913238, COSV58487495; called by muse, mutect2, varscan2
- KRT78 | c.423G>A p.T141= | Silent (SNP) | VAF 199/328 reads (61%) | catalogued as rs116002883; called by muse, mutect2, varscan2
- L3MBTL4 | c.399C>T p.S133= | Silent (SNP) | VAF 155/352 reads (44%) | catalogued as COSV99531972; called by muse, mutect2, varscan2
- LMO7 | c.2916C>T p.P972= (on ENST00000357063; = p.P653= on NM_005358.5) | Silent (SNP) | VAF 204/410 reads (50%) | catalogued as rs371242913; called by muse, mutect2, varscan2
- LRFN2 | c.78C>T p.V26= | Silent (SNP) | VAF 93/343 reads (27%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1062C>T p.F354= | Silent (SNP) | VAF 91/162 reads (56%) | catalogued as rs868643467; called by muse, mutect2, varscan2
- LRRN2 | c.1554C>T p.L518= | Silent (SNP) | VAF 242/338 reads (72%) | called by muse, mutect2, varscan2
- MAGEC2 | c.27C>T p.F9= | Silent (SNP) | VAF 206/207 reads (100%) | catalogued as COSV99909748; called by muse, mutect2, varscan2
- MGAM2 | c.3070C>T p.L1024= | Silent (SNP) | VAF 172/324 reads (53%) | called by muse, mutect2, varscan2
- MSX1 | c.831C>T p.P277= | Silent (SNP) | VAF 317/480 reads (66%) | called by muse, mutect2, varscan2
- MTHFR | c.594C>T p.P198= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.12276C>T p.I4092= | Silent (SNP) | VAF 169/400 reads (42%) | catalogued as rs756263109, COSV67465143; called by muse, mutect2, varscan2
- MYO18B | c.4794A>G p.R1598= | Silent (SNP) | VAF 16/384 reads (4%) | called by muse, mutect2
- MYO1F | c.2964C>T p.S988= | Silent (SNP) | VAF 221/531 reads (42%) | catalogued as rs1157388117, COSV57795253; called by muse, mutect2, varscan2
- MYO7A | c.5394G>A p.Q1798= | Silent (SNP) | VAF 211/434 reads (49%) | called by muse, mutect2, varscan2
- MYT1L | c.993G>A p.R331= | Silent (SNP) | VAF 246/492 reads (50%) | catalogued as COSV67724939; called by muse, varscan2
- NCF1 | c.537G>A p.T179= | Silent (SNP) | VAF 103/227 reads (45%) | catalogued as rs781784127; called by muse, mutect2, varscan2
- NHSL2 | c.2122C>T p.L708= (on ENST00000510661; = p.L1074= on NM_001013627.2) | Silent (SNP) | VAF 109/112 reads (97%) | called by muse, mutect2, varscan2
- NKX2-3 | c.259C>T p.L87= | Silent (SNP) | VAF 192/194 reads (99%) | catalogued as COSV104419505; called by muse, mutect2, varscan2
- NLRP9 | c.1476G>A p.G492= | Silent (SNP) | VAF 219/432 reads (51%) | catalogued as COSV60464408; called by muse, mutect2, varscan2
- NRIP1 | c.2148C>T p.L716= | Silent (SNP) | VAF 175/591 reads (30%) | catalogued as rs185987444; called by muse, mutect2, varscan2
- NRXN2 | c.4050G>A p.A1350= | Silent (SNP) | VAF 298/609 reads (49%) | catalogued as rs761962421, COSV55457036; called by muse, mutect2, varscan2
- NXPE2 | c.1299G>A p.R433= | Silent (SNP) | VAF 166/347 reads (48%) | called by muse, mutect2, varscan2
- OPHN1 | c.1821G>A p.L607= | Silent (SNP) | VAF 145/148 reads (98%) | called by muse, mutect2, varscan2
- OR2AP1 | c.663G>A p.K221= | Silent (SNP) | VAF 89/284 reads (31%) | catalogued as rs747269576; called by muse, mutect2, varscan2
- OR2F1 | c.675C>T p.I225= | Silent (SNP) | VAF 144/324 reads (44%) | catalogued as rs1160336390; called by muse, mutect2, varscan2
- OR4C5 | c.195C>T p.I65= | Silent (SNP) | VAF 202/427 reads (47%) | called by muse, mutect2, varscan2
- OR4E1 | c.108C>T p.L36= | Silent (SNP) | VAF 135/301 reads (45%) | called by muse, mutect2, varscan2
- OR51S1 | c.780C>T p.I260= | Silent (SNP) | VAF 218/628 reads (35%) | catalogued as rs866618850, COSV59059712; called by muse, mutect2
- OR5B3 | c.663C>T p.I221= | Silent (SNP) | VAF 112/322 reads (35%) | catalogued as rs146606547; called by muse, mutect2
- OR8J1 | c.882G>A p.R294= | Silent (SNP) | VAF 145/333 reads (44%) | catalogued as rs759451788, COSV57316805; called by muse, mutect2, varscan2
- PAPLN | c.1791C>T p.G597= (on ENST00000554301; = p.G570= on NM_173462.4) | Silent (SNP) | VAF 402/760 reads (53%) | catalogued as rs766691028; called by mutect2, varscan2
- PBXIP1 | c.1141C>T p.L381= | Silent (SNP) | VAF 105/356 reads (29%) | called by muse, mutect2, varscan2
- PBXIP1 | c.1140C>T p.F380= | Silent (SNP) | VAF 105/353 reads (30%) | catalogued as COSV63777595; called by muse, mutect2, varscan2
- PCDHGA8 | c.1383C>T p.I461= | Silent (SNP) | VAF 371/372 reads (100%) | catalogued as COSV53988605; called by muse, mutect2, varscan2
- PDE11A | c.2787G>A p.K929= | Silent (SNP) | VAF 148/292 reads (51%) | catalogued as rs1281037960; called by muse, mutect2, varscan2
- PLIN3 | c.1191C>A p.A397= | Silent (SNP) | VAF 197/417 reads (47%) | catalogued as rs752138898; called by muse, mutect2, varscan2
- POTEA | c.291G>A p.K97= | Silent (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- POTEF | c.390G>A p.E130= | Silent (SNP) | VAF 148/320 reads (46%) | called by muse, mutect2, varscan2
- PPEF2 | c.2253T>C p.G751= | Silent (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
- PPP3CC | c.54C>T p.V18= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs201721168; called by muse, mutect2, varscan2
- PSG4 | c.759G>A p.E253= | Silent (SNP) | VAF 91/188 reads (48%) | called by muse, mutect2, varscan2
- PSMC1 | c.1080G>A p.T360= | Silent (SNP) | VAF 226/424 reads (53%) | catalogued as rs781271442, COSV99728436; called by muse, mutect2, varscan2
- PSMD6 | c.132C>T p.A44= | Silent (SNP) | VAF 101/355 reads (28%) | called by muse, mutect2, varscan2
- PTPRD | c.4311G>A p.G1437= | Silent (SNP) | VAF 291/293 reads (99%) | catalogued as rs1251038630, COSV100642788; called by muse, mutect2, varscan2
- RGS9BP | c.522C>T p.T174= | Silent (SNP) | VAF 253/556 reads (46%) | catalogued as rs769710405; called by muse, mutect2, varscan2
- RHBDD2 | c.642C>T p.L214= | Silent (SNP) | VAF 178/366 reads (49%) | catalogued as rs782573934, COSV50087584; called by muse, mutect2, varscan2
- RNF165 | c.348C>T p.A116= | Silent (SNP) | VAF 186/356 reads (52%) | called by muse, mutect2, varscan2
- RNF39 | c.268C>T p.L90= | Silent (SNP) | VAF 204/659 reads (31%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.783G>A p.G261= | Silent (SNP) | VAF 186/189 reads (98%) | catalogued as rs766456537; called by muse, mutect2, varscan2
- SBK3 | c.1056G>A p.T352= | Silent (SNP) | VAF 229/454 reads (50%) | catalogued as rs1005087489; called by muse, mutect2, varscan2
- SCUBE3 | c.2628G>A p.E876= | Silent (SNP) | VAF 133/214 reads (62%) | called by muse, mutect2, varscan2
- SEMA4B | c.1419C>T p.L473= | Silent (SNP) | VAF 170/271 reads (63%) | called by muse, mutect2, varscan2
- SIAE | c.285C>T p.F95= | Silent (SNP) | VAF 149/323 reads (46%) | catalogued as rs147638217; called by muse, mutect2, varscan2
- SIGLEC12 | c.528C>A p.P176= (on ENST00000291707 / NM_053003.4; = p.P58= on NM_033329.2) | Silent (SNP) | VAF 15/468 reads (3%) | called by muse, mutect2
- SLA2 | c.348G>A p.G116= | Silent (SNP) | VAF 177/385 reads (46%) | called by muse, mutect2, varscan2
- SLC22A9 | c.1140C>T p.F380= | Silent (SNP) | VAF 137/331 reads (41%) | catalogued as COSV54165816; called by muse, mutect2, varscan2
- SLC5A5 | c.1701C>T p.L567= | Silent (SNP) | VAF 194/372 reads (52%) | catalogued as rs375404000, COSV55835703; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORL1 | c.1470G>A p.R490= | Silent (SNP) | VAF 148/341 reads (43%) | called by muse, mutect2, varscan2
- SP100 | c.2385C>T p.F795= | Silent (SNP) | VAF 144/269 reads (54%) | catalogued as rs543288909, COSV60844606; called by muse, mutect2, varscan2
- SPG11 | c.2058C>T p.L686= | Silent (SNP) | VAF 97/164 reads (59%) | catalogued as COSV55991943; called by muse, mutect2, varscan2
- SPIDR | c.42G>A p.R14= | Silent (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- SPTA1 | c.3471C>T p.I1157= | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV100934121; called by muse, mutect2, varscan2
- STXBP2 | c.888C>T p.I296= | Silent (SNP) | VAF 143/301 reads (48%) | catalogued as rs1350527680, COSV99657421; called by muse, mutect2, varscan2
- TAF3 | c.2421C>T p.L807= | Silent (SNP) | VAF 317/320 reads (99%) | catalogued as rs761732712, COSV60206814; called by muse, mutect2, varscan2
- TCF4 | c.1578G>A p.T526= | Silent (SNP) | VAF 167/373 reads (45%) | catalogued as rs774527851, COSV61895509; called by muse, mutect2, varscan2
- TIMELESS | c.828T>G p.S276= | Silent (SNP) | VAF 62/177 reads (35%) | called by muse, mutect2, varscan2
- TMEM132E | c.1884G>A p.L628= (on ENST00000321639; = p.L718= on NM_001304438.2) | Silent (SNP) | VAF 182/396 reads (46%) | catalogued as COSV58695152; called by muse, mutect2, varscan2
- TNFRSF17 | c.450G>A p.E150= | Silent (SNP) | VAF 165/374 reads (44%) | catalogued as rs1259565059; called by mutect2, varscan2
- TNFSF8 | c.633C>T p.F211= | Silent (SNP) | VAF 319/320 reads (100%) | catalogued as rs778760383; called by muse, mutect2, varscan2
- TNK2 | c.1221C>T p.I407= | Silent (SNP) | VAF 97/323 reads (30%) | called by muse, mutect2, varscan2
- TRABD2B | c.744G>A p.T248= | Silent (SNP) | VAF 118/327 reads (36%) | catalogued as rs918051247; called by muse, mutect2, varscan2
- TSHZ1 | c.738C>T p.F246= (on ENST00000580243 / NM_001308210.2; = p.F201= on NM_005786.6) | Silent (SNP) | VAF 180/362 reads (50%) | called by muse, varscan2
- TTC19 | c.384G>A p.Q128= | Silent (SNP) | VAF 127/311 reads (41%) | catalogued as COSV55422824; called by muse, mutect2, varscan2
- TTC34 | c.2844C>T p.A948= | Silent (SNP) | VAF 297/453 reads (66%) | catalogued as rs780050508; called by muse, mutect2, varscan2
- TTN | c.101808G>A p.K33936= (on ENST00000591111; = p.K26512= on NM_003319.4) | Silent (SNP) | VAF 174/350 reads (50%) | catalogued as COSV59990384; called by muse, mutect2, varscan2
- UBE4B | c.3297C>T p.I1099= (on ENST00000343090 / NM_001105562.3; = p.I970= on NM_006048.5) | Silent (SNP) | VAF 81/278 reads (29%) | called by muse, mutect2, varscan2
- UGT2A3 | c.1386C>T p.I462= | Silent (SNP) | VAF 236/341 reads (69%) | catalogued as rs755442651; called by muse, mutect2, varscan2
- VGLL3 | c.645G>A p.V215= | Silent (SNP) | VAF 240/363 reads (66%) | catalogued as rs1262306356, COSV101052088; called by muse, mutect2, varscan2
- WNT2 | c.402C>T p.S134= | Silent (SNP) | VAF 161/374 reads (43%) | catalogued as COSV99625849; called by muse, mutect2, varscan2
- YME1L1 | c.1167C>A p.A389= (on ENST00000326799 / NM_139312.3; = p.A332= on NM_014263.4) | Silent (SNP) | VAF 138/140 reads (99%) | called by mutect2, varscan2
- ZAR1 | c.240G>A p.R80= | Silent (SNP) | VAF 144/460 reads (31%) | catalogued as rs1406762909; called by muse, mutect2, varscan2
- ZFPM2 | c.3264G>A p.E1088= | Silent (SNP) | VAF 87/283 reads (31%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.648C>T p.S216= | Silent (SNP) | VAF 169/404 reads (42%) | catalogued as rs1479647184; called by muse, mutect2, varscan2
- ZMYM3 | c.70C>T p.L24= | Silent (SNP) | VAF 45/349 reads (13%) | called by muse, mutect2, varscan2
- ZNF605 | c.1390C>T p.L464= | Silent (SNP) | VAF 20/402 reads (5%) | catalogued as rs775288594; called by muse, mutect2
- C4orf50 | chr4:5990691 G>A | 5'Flank (SNP) | VAF 228/350 reads (65%) | called by muse, mutect2, varscan2
- CD163 | c.47-162A>G | Intron (SNP) | VAF 73/259 reads (28%) | catalogued as rs969953393; called by muse, mutect2, varscan2
- DAZL | c.3+707G>A | Intron (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- DIRC1 | n.352C>T | RNA (SNP) | VAF 183/422 reads (43%) | catalogued as rs745669182; called by muse, mutect2, varscan2
- EEF1D | c.-7-2464C>T | Intron (SNP) | VAF 274/416 reads (66%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2465C>A | Intron (SNP) | VAF 270/411 reads (66%) | called by muse, mutect2, varscan2
- FBXW7 | c.501+29031A>C | Intron (SNP) | VAF 183/293 reads (62%) | called by muse, mutect2, varscan2
- GLYATL1 | c.-102G>A | 5'UTR (SNP) | VAF 128/286 reads (45%) | catalogued as COSV55609865; called by muse, mutect2, varscan2
- GSDME | c.990+47G>A | Intron (SNP) | VAF 193/421 reads (46%) | called by muse, mutect2, varscan2
- HSPH1 | chr13:31162076 G>A | 5'Flank (SNP) | VAF 210/462 reads (45%) | called by muse, mutect2, varscan2
- KCNK12 | c.*8536C>T | 3'UTR (SNP) | VAF 196/418 reads (47%) | catalogued as rs776464665; called by muse, mutect2, varscan2
- MRPL4 | c.740-407C>T | Intron (SNP) | VAF 198/382 reads (52%) | called by muse, mutect2, varscan2
- NACA | c.70+3994C>T | Intron (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- NADK | c.263+2123A>T | Intron (SNP) | VAF 113/328 reads (34%) | called by muse, mutect2, varscan2
- NEB | c.11602-3158C>G | Intron (SNP) | VAF 163/613 reads (27%) | called by muse, mutect2
- OAS3 | c.460+43C>T | Intron (SNP) | VAF 86/334 reads (26%) | catalogued as rs779823267; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441859 G>A | 5'Flank (SNP) | VAF 58/646 reads (9%) | called by muse, mutect2
- PRDX6 | chr1:173476832 G>A | 5'Flank (SNP) | VAF 122/376 reads (32%) | called by muse, mutect2, varscan2
- PRF1 | c.*224C>T | 3'UTR (SNP) | VAF 105/105 reads (100%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1726G>A | Intron (SNP) | VAF 284/418 reads (68%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119069179 C>T | 5'Flank (SNP) | VAF 121/247 reads (49%) | catalogued as rs782544005; called by muse, mutect2, varscan2
- XKR6 | c.*1G>A | 3'UTR (SNP) | VAF 152/212 reads (72%) | called by muse, mutect2, varscan2
- ZNF415 | c.136+590G>A | Intron (SNP) | VAF 114/268 reads (43%) | called by muse, mutect2, varscan2
